Gene-level copy-number profile of tumor specimen BLGSP-71-06-00160-01B from CGCI case BLGSP-71-06-00160, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS.
Specimen BLGSP-71-06-00160-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9961307a-184c-4c35-9ba1-ddd33bcc0ba5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00160-12A (buccal cell normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,735 have no estimate.
https://portal.gdc.cancer.gov/files/220f57d7-5e09-4d4b-8421-7c1a0ee4fa45

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 69; copy number 1: 3,321; copy number 2: 51,794; copy number 3: 3,677; copy number 4: 11; copy number 5: 3; copy number 7: 4; copy number 8: 8; copy number 15: 1.

Homozygous deletions (total copy number 0; autosomes only): 69 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,885,397–88,992,931, 8 genes (within-gene range 0–1): IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV3-7, IGKV1-8.
- chr2:89,027,171–89,027,731, 1 gene (within-gene range 0–1): IGKV3-11.
- chr14:105,851,705–106,108,464, 59 genes (within-gene range 0–1): IGHM, MIR4539, MIR4507, MIR4538, MIR4537, IGHJ6, IGHJ3P, IGHJ5, IGHJ4, IGHJ3, IGHJ2P, IGHJ2, IGHJ1, IGHD7-27, IGHJ1P, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7, IGHV3-64D, IGHV5-10-1.
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–1): IGHVIII-16-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:145,214,851–145,242,124, 3 genes, copy number 5: AC241585.2, AC241585.1, PPIAL4D.
- chr1:149,345,661–149,556,361, 4 genes, copy number 8: SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19.
- chr2:89,309,898–89,600,680, 4 genes, copy number 7: IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA.
- chr7:63,348,861–63,359,306, 4 genes, copy number 8 (within-gene range 5–8): AC006455.5, AC006455.2, AC006455.3, AC006455.4.
- chr9:65,282,101–65,285,209, 1 gene, copy number 15: FOXD4L5.

Autosomal genes at a single copy (total copy number 1): 470. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
